Somatic mutation profile of tumor specimen MBCProject_1852_T1_WES (aliquot MBCProject_1852_T1_WES_1) from CMI case MBCProject_1852, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 35.9 years (13,097 days).
Specimen MBCProject_1852_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f05a987e-d4e8-403d-a31c-f7342fca7e00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1852_SALIVA (Saliva), aliquot MBCProject_1852_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcea6905-44ff-404a-9ed5-a1e3150e52b4

The open-access MAF lists 91 somatic variants for this specimen: 70 protein-altering or splice-affecting, 15 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 15, Intron 3, Splice Region 2, 3'UTR 2, Frame Shift Ins 2, Nonsense Mutation 2, Frame Shift Del 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1817A>G p.Y606C | Missense Mutation (SNP) | VAF 8/114 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV57305816; called by muse, mutect2
- ALDH3A1 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as rs536804477; called by muse, mutect2, varscan2
- AP002512.3 | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV54406908; called by muse, mutect2, varscan2
- ASPM | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as rs1227283442, COSV99659125; called by muse, mutect2
- ATP1A3 | c.1174G>A p.A392T (on ENST00000545399 / NM_001256214.2; = p.A379T on NM_152296.5) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV57488799; called by muse, varscan2
- AVPR1A | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs1424319046, COSV54547616; called by muse, mutect2
- CADM3 | c.892G>A p.G298S (on ENST00000368125 / NM_001127173.3; = p.G332S on NM_021189.5) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.153); catalogued as rs1557938790, COSV100930316, COSV63686125; called by muse, mutect2, varscan2
- CDON | c.2713C>T p.Q905* | Nonsense Mutation (SNP) | VAF 24/173 reads (14%) | catalogued as rs774393949; called by muse, mutect2, varscan2
- DIP2B | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs900549141, COSV56593046; called by muse, mutect2
- EFCAB6 | c.2663T>C p.F888S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1348923133; called by muse, mutect2, varscan2
- EVPL | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV56913459; called by muse, varscan2
- FOXG1 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); catalogued as rs1287203413, COSV57396534; called by muse, mutect2
- GATA3 | c.990dup p.N331Efs*21 | Frame Shift Ins (INS) | VAF 148/526 reads (28%) | catalogued as COSV60516089, COSV60517561; called by mutect2, pindel, varscan2
- GDF10 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs782623944; called by muse, mutect2
- GXYLT1 | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55132546; called by muse, mutect2
- ITGA3 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as rs1159713169; called by muse, mutect2
- KBTBD4 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1488259580, COSV55454583; called by muse, mutect2
- KCNAB3 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.063); catalogued as rs1326136391; called by muse, mutect2
- NIPBL | c.5331C>T p.I1777= | Splice Region (SNP) | VAF 39/379 reads (10%) | catalogued as COSV99242344; called by muse, mutect2, varscan2
- NOP2 | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs746254580; called by muse, mutect2, varscan2
- OBI1 | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1390994210; called by muse, mutect2, varscan2
- PKD1 | c.4273C>T p.R1425C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs773227281, CX1210802, COSV51924045; called by muse, mutect2, varscan2
- PNMA8A | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.674); catalogued as rs565739284, COSV58137993; called by muse, mutect2, varscan2
- RGS18 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs993767738; called by muse, mutect2
- STOX1 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV53817872; called by muse, mutect2
- WAPL | c.719A>G p.D240G | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.111); catalogued as rs780227125; called by muse, mutect2, varscan2
- ZNF462 | c.4726G>A p.A1576T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs555892467; called by muse, mutect2, varscan2
- ZNF469 | c.3563G>A p.R1188H (on ENST00000437464; = p.R1216H on NM_001367624.2) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs945136840; called by muse, mutect2, varscan2
- ACOT2 | c.297_298insGAC p.S99_L100insD | In Frame Ins (INS) | VAF 21/144 reads (15%) | called by mutect2, pindel, varscan2
- AKT1S1 | c.155G>A p.G52E (on ENST00000344175 / NM_001098633.4; = p.G72E on NM_032375.5) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- AP2B1 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); called by muse, mutect2
- ASCC1 | c.614A>C p.K205T (on ENST00000342444 / NM_001369085.1; = p.K177T on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BTBD11 | c.1406C>A p.T469N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- C3orf70 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCT4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by muse, mutect2
- COLGALT1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIPK2A | c.1241C>G p.A414G | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2
- DYNC1H1 | c.10285A>C p.K3429Q | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- EML3 | c.22+5G>C | Splice Region (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- FAM111A | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM47A | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAT4 | c.6997A>T p.M2333L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO24 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- GPATCH4 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- HCN2 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- HECTD2 | c.1322T>G p.L441W | Missense Mutation (SNP) | VAF 23/327 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HERC2 | c.7931A>C p.K2644T | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IHH | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by mutect2, varscan2
- KCNQ5 | c.404T>A p.L135H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- KLHL11 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MAGI3 | c.2917A>G p.R973G | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- MARS2 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- MDN1 | c.16552A>C p.N5518H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MMS19 | c.497del p.L166Qfs*4 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel
- MYCBP2 | c.11915A>G p.D3972G (on ENST00000357337; = p.D4010G on NM_015057.5) | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PFKP | c.2255_2258dup p.K753Nfs*18 | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- PIGH | c.443A>T p.H148L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POF1B | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.194); called by muse, mutect2
- PRKG1 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RFX5 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.172); called by muse, mutect2
- RPRD2 | c.3355C>A p.H1119N | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SCAPER | c.2646G>T p.R882S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by mutect2, varscan2
- SDHA | c.425T>A p.M142K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SETD2 | c.7498A>T p.T2500S | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2
- SLC4A5 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SMS | c.349G>C p.G117R | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOSTDC1 | c.151A>C p.N51H | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNXB | c.9357C>G p.D3119E (on ENST00000647633; = p.D2872E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2
- TRIP11 | c.5128G>C p.E1710Q | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.269); called by muse, mutect2
- USF3 | c.3136C>T p.H1046Y | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.454); called by muse, mutect2
- C6orf118 | c.96G>A p.T32= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs770663869, COSV57812404; called by mutect2, varscan2
- CHD3 | c.5412G>C p.L1804= (on ENST00000330494 / NM_001005273.3; = p.L1770= on NM_005852.4) | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- COL25A1 | c.1041T>C p.G347= | Silent (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- CYFIP2 | c.3393C>G p.P1131= (on ENST00000616178 / NM_001291722.2; = p.P1106= on NM_014376.4) | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- DKC1 | c.492A>G p.E164= | Silent (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- DOCK11 | c.2736A>G p.L912= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- HEPH | c.2637C>T p.S879= (on ENST00000343002; = p.S612= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs748396986, COSV57958462; called by muse, mutect2, varscan2
- MLPH | c.609C>T p.D203= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as rs1020930344; called by muse, mutect2, varscan2
- PRKCG | c.1233C>T p.G411= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54731055; called by muse, mutect2, varscan2
- PRRC2C | c.2802G>A p.T934= (on ENST00000367742; = p.T932= on NM_015172.4) | Silent (SNP) | VAF 27/185 reads (15%) | catalogued as rs751500349; called by muse, mutect2, varscan2
- RYR1 | c.3951C>T p.P1317= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs745447236, COSV62099023; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC32A1 | c.867G>A p.A289= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs760283518; called by muse, mutect2, varscan2
- TANC2 | c.1248C>G p.L416= | Silent (SNP) | VAF 39/416 reads (9%) | called by muse, mutect2
- TENM1 | c.1614A>T p.G538= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- WT1 | c.228C>T p.S76= | Silent (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- HAVCR1 | c.*79A>T | 3'UTR (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- LINC01545 | n.215T>C | RNA (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- PAXIP1-AS2 | n.283+244C>T | Intron (SNP) | VAF 9/84 reads (11%) | catalogued as rs1418470190; called by muse, mutect2, varscan2
- RPL36A | c.300+27A>G | Intron (SNP) | VAF 21/46 reads (46%) | catalogued as rs1555984192; called by muse, mutect2, varscan2
- TNIP3 | c.492+48T>A | Intron (SNP) | VAF 13/143 reads (9%) | called by muse, mutect2
- VAPB | c.*1724C>T | 3'UTR (SNP) | VAF 12/128 reads (9%) | catalogued as rs772258342; called by muse, mutect2, varscan2
